Somatic mutation profile of tumor specimen MP2PRT-PASYLA-TBP1-A (aliquot MP2PRT-PASYLA-TBP1-A-1-0-D-A83O-36) from MP2PRT case MP2PRT-PASYLA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.2 years (1,185 days).
Specimen MP2PRT-PASYLA-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb07fe53-4506-4767-ac80-b1d0c746b377.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASYLA-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASYLA-NB1-A-1-0-D-A83O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bb0ccef2-b160-4a3d-a68b-6ba2ae2c46fc

The open-access MAF lists 30 somatic variants for this specimen: 19 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 10, Nonsense Mutation 3, Frame Shift Ins 3, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.4496T>A p.L1499Q | Missense Mutation (SNP) | VAF 94/327 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52115693, COSV52125172, COSV52125754; called by muse, mutect2, varscan2
- KRAS | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 46/148 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as rs1057519725, COSV55498939; ClinVar: not provided / pathogenic; called by mutect2, varscan2
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 67/285 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FAT1 | c.3208C>T p.R1070* | Nonsense Mutation (SNP) | VAF 39/374 reads (10%) | catalogued as rs1183516785, COSV71674659; called by muse, mutect2, varscan2
- MYO9B | c.2104G>A p.G702R | Missense Mutation (SNP) | VAF 165/334 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs368425030; called by muse, mutect2, varscan2
- TEX36 | c.214G>A p.V72M | Missense Mutation (SNP) | VAF 38/206 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.023); catalogued as rs574167239, COSV100917778; called by muse, varscan2
- TYR | c.1562A>G p.Y521C | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.594); catalogued as COSV54486684, COSV99635460; called by muse, mutect2, varscan2
- ABCC5 | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.526A>G p.N176D | Missense Mutation (SNP) | VAF 64/714 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.1); called by muse, mutect2
- CNTNAP2 | c.488C>A p.P163H | Missense Mutation (SNP) | VAF 24/318 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CYLC2 | c.550G>T p.G184C | Missense Mutation (SNP) | VAF 82/363 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- FOXP2 | c.35A>T p.N12I | Missense Mutation (SNP) | VAF 14/259 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2
- KMT2A | c.1276C>T p.R426W | Missense Mutation (SNP) | VAF 62/294 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- KMT2D | c.6142_6149dup p.R2050Sfs*47 | Frame Shift Ins (INS) | VAF 38/250 reads (15%) | called by mutect2, varscan2
- KMT2D | c.2271_2272insA p.E758Rfs*9 | Frame Shift Ins (INS) | VAF 108/448 reads (24%) | called by mutect2, pindel*, varscan2
- PAXBP1 | c.1760A>T p.D587V | Missense Mutation (SNP) | VAF 72/273 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PIGW | c.1314_1315insGGGGCCTTCCG p.C439Gfs*6 | Frame Shift Ins (INS) | VAF 46/380 reads (12%) | called by mutect2, pindel, varscan2
- PRPF6 | c.1567C>T p.Q523* | Nonsense Mutation (SNP) | VAF 137/268 reads (51%) | called by muse, mutect2, varscan2
- ZNF831 | c.3290G>A p.W1097* | Nonsense Mutation (SNP) | VAF 81/362 reads (22%) | called by muse, mutect2, varscan2
- ADAM18 | c.2202C>T p.S734= | Silent (SNP) | VAF 25/172 reads (15%) | catalogued as rs775433052; called by muse, mutect2, varscan2
- ASB16 | c.651G>A p.A217= | Silent (SNP) | VAF 86/580 reads (15%) | called by muse, mutect2, varscan2
- ASXL3 | c.5019C>T p.H1673= | Silent (SNP) | VAF 47/376 reads (13%) | catalogued as rs760483583; called by muse, varscan2
- KCNJ11 | c.462C>T p.I154= | Silent (SNP) | VAF 63/286 reads (22%) | catalogued as rs145757832; called by muse, mutect2, varscan2
- KHDC4 | c.1092C>T p.Y364= | Silent (SNP) | VAF 54/228 reads (24%) | called by muse, mutect2, varscan2
- KRT33A | c.693G>A p.Q231= | Silent (SNP) | VAF 85/478 reads (18%) | catalogued as rs764410261; called by muse, varscan2
- PLSCR2 | c.21C>T p.L7= | Silent (SNP) | VAF 34/169 reads (20%) | called by muse, mutect2, varscan2
- RNF150 | c.1179C>T p.D393= | Silent (SNP) | VAF 58/447 reads (13%) | catalogued as rs761038881, COSV100153456; called by muse, mutect2, varscan2
- SLITRK3 | c.1455G>A p.L485= | Silent (SNP) | VAF 66/266 reads (25%) | called by muse, mutect2, varscan2
- ZFHX3 | c.900C>T p.H300= | Silent (SNP) | VAF 50/244 reads (20%) | catalogued as rs150869238; called by muse, varscan2
- KCNQ1 | c.1393+19827C>T | Intron (SNP) | VAF 46/205 reads (22%) | called by muse, mutect2, varscan2
